CCDI case PBCLUA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/943d69cd-455c-4345-8f39-0f360d56d060

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 6.1 years (2,211 days).

Biospecimens (3 samples)
- Sample 0DVPON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVPP0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVXF1: Tissue type: Tumor; Specimen type: Solid Tissue.
